Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A18C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A18C-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Postmenopausal.

PROCEDURE: TLH, BSO.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: Not provided.

PRIOR MALIGNANCY: Not provided.

CHEMORADIATION THERAPY: Not provided.

OTHER DISEASES: Not provided.

Adenocarcinoma, Endometrioid, NOS 8380/3

Site Code: Endometrium C541

2/15/10
JRUUID: 2A6FB6E4-7FBF-45EA-B9B0-C4EDC78C35E2

**FINAL DIAGNOSIS:****PART 1: LEFT PELVIC LYMPH NODE, DISSECTION -**

ELEVEN LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/11).

PART 2: LEFT PELVIC LYMPH NODES, B, DISSECTION -

A. FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

B. NO LYMPHOID PARENCHYMA IS IDENTIFIED.

PART 3: LEFT PERIAORTIC LYMPH NODES, DISSECTION -

TWO LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/2).

PART 4: RIGHT PELVIC LYMPH NODES, DISSECTION -

FOURTEEN LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/14).

PART 5: RIGHT PERIAORTIC LYMPH NODES, DISSECTION -

THREE LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/3).

PART 6: UTERUS, CERVIX, BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -A. ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE 2, NUCLEAR GRADE 2, INVOLVES 95% OF ENDOMETRIAL SURFACE ARISES IN A BACKGROUND OF COMPLEX ATYPICAL HYPERPLASIA.

B. TUMOR INVADERS 0.3 CM OF 2.3 CM MYOMETRIUM (~13%).

C. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.

D. CERVIX AND BILATERAL ADNEXA, NEGATIVE FOR TUMOR.

E. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYSTS.

F. RIGHT OVARY WITH SURFACE EPITHELIAL INCLUSIONS, AND FOCAL SURFACE ADHESIONS.

G. BILATERAL OVARIES WITH MILD STROMAL HYPERPLASIA.

H. CERVIX WITH MESONEPHRIC REMNANTS.

I. PATHOLOGIC STAGE: T1a N0 MX.

J. FIGO STAGE: IA G2.

COMMENT:

Correlated with companion negative pelvic wash

Prior biopsy results of endometrioid carcinoma with focal high-grade component are noted. Specimen is extensively sampled and there is no evidence of high-grade malignant neoplasm.

CASE SYNOPSIS:**SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY****SPECIMENS****TUMOR TYPE:** Endometrioid adenocarcinoma, NOS**HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:**

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE: Moderately differentiated**NUCLEAR GRADE:** Grade 2**TUMOR SIZE:** Maximum dimension: 40 mm**PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:**

Anterior endomyometrium: 95 %, Posterior endomyometrium: 95 %

DEPTH OF INVASION: Less than 1/2 thickness of myometrium**ANGIOLYMPHATIC INVASION:** No**PRE-NEOPLASTIC CONDITIONS:** Complex endometrial hyperplasia with atypia**LYMPH NODES POSITIVE:** Number of lymph nodes positive: 0**LYMPH NODES EXAMINED:** Total number of lymph nodes examined: 30**T STAGE, PATHOLOGIC:** pT1a**N STAGE, PATHOLOGIC:** pN0**M STAGE, PATHOLOGIC:** Not applicable**FIGO STAGE:** IA

Source: NCI Genomic Data Commons file 595cae9f-7ed5-4e82-a70c-170fa99bfd0a (TCGA-BG-A18C.2A6FB6E4-7FBF-45EA-B9B0-C4EDC78C35E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).